CGCI case BLGSP-71-30-00653 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59e5b2fa-dd22-4a20-ab29-5e52b681c9e9

Demographics
Sex at birth: male; Age at index: 45 years; Vital status: Dead; Days to death: 12 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: primary; Age at diagnosis: 45.4 years (16,566 days); Year of diagnosis: 2010; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4 days; Ann Arbor extranodal involvement: No; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Inguinal.
   Pathology details: Lymph node involved site: Inguinal; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 3 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 4 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MIB1 (IHC): Positive.
- MYC translocation (FISH): Abnormal, NOS.
- Test (IHC): Negative; Specialized molecular test: TdT.
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: Risk factors: Hepatitis C Infection.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00653-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00653-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00653-01-CD3: Tissue microarray coordinates: I4,J4.
  Slide BLGSP-71-30-00653-01-CD10: Tissue microarray coordinates: I4,J4.
  Slide BLGSP-71-30-00653-01-EBER: Tissue microarray coordinates: I4,J4.
  Slide BLGSP-71-30-00653-01-BCL2: Tissue microarray coordinates: I4,J4.
  Slide BLGSP-71-30-00653-01-BCL6: Tissue microarray coordinates: I4,J4.
  Slide BLGSP-71-30-00653-01-Ki67: Tissue microarray coordinates: I4,J4.
  Slide BLGSP-71-30-00653-01-CD20: Tissue microarray coordinates: I4,J4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease, History relevant infectious diseases: History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: Yes.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: TdT.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: MIB-1.
- Tests performed: Immunophenotypic analysis method: Immunohistochemistry; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00653-01A-01E-0001-01:
- % tumour: 80
